Gene-level copy-number profile of tumor specimen TCGA-CF-A9FF-01A from TCGA case TCGA-CF-A9FF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 52.6 years (19,195 days).
Specimen TCGA-CF-A9FF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.f15ec6db-f2cc-4625-a73f-962bb976b9ad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CF-A9FF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d227230a-3cd4-4039-8ca7-24a04d4af1a7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,860; copy number 3: 3,889; copy number 4: 45,534; copy number 5: 1,840; copy number 6: 3,332; copy number 7: 169; copy number 10: 101; copy number 15: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CF-A9FF-01A-11D-A38F-01): tumor purity 0.73, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 195 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,995,211–163,769,691, 94 genes, copy number 15 (broad region; genes not listed).
- chr1:164,555,584–168,582,069, 97 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr16:9,541,970–9,676,843, 4 genes, copy number 10: AC007221.1, RNA5SP403, RNA5SP404, AC007218.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
